Somatic mutation profile of tumor specimen MP2PRT-PARAUT-TMP1-A (aliquot MP2PRT-PARAUT-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARAUT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,055 days).
Specimen MP2PRT-PARAUT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15582b9e-ddf6-4be0-a98b-e1da283fd96e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARAUT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARAUT-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87ce978d-6720-4e98-afab-8dde998b0fc5

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR4C11 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as rs367557405; called by muse, mutect2, varscan2
- TENM3 | c.6110C>T p.T2037M | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs377755577; called by muse, mutect2, varscan2
- CLIC6 | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PLD1 | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 122/344 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TOX3 | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 135/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UGT2B28 | c.998A>C p.Q333P | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WASHC3 | c.107_108insTGACTGC p.T37Dfs*15 | Frame Shift Ins (INS) | VAF 106/338 reads (31%) | called by mutect2, pindel, varscan2
- WDPCP | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 122/299 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
